CCDI case PBCMLS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/9ea921a0-6b90-4bc2-a2b1-bc9d247f8cc2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.5 years (2,356 days).

Biospecimens (2 samples)
- Sample 0DVHAY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVHB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
